Gene-level copy-number profile of tumor specimen TCGA-2G-AAKO-05A from TCGA case TCGA-2G-AAKO, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Tissue or organ of origin: Testis, NOS.
Specimen TCGA-2G-AAKO-05A: Sample type: Additional - New Primary; Tissue type: Tumor; Tumor descriptor: New Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.7bd03897-b4fc-4502-8d16-4d15ad94250f.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2G-AAKO-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 349 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fa484156-f793-4b4f-821e-90d670022cb3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,395; copy number 1: 10,742; copy number 2: 42,073; copy number 3: 4,999; copy number 4: 17; copy number 5: 5; copy number 9: 43.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2G-AAKO-05A-11D-A42X-01): tumor purity 0.41, ploidy 3.99, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,590,487–248,645,278, 5 genes: OR2T10, Y_RNA, AC098483.2, OR2T11, OR2T35.
- chr4:68,509,441–68,568,527, 2 genes: UGT2B29P, UGT2B17.
- chr22:32,188,400–32,188,487, 1 gene: AL008723.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 45 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 2 genes, copy number 9 (within-gene range 2–9): MALLP2, AC244205.1.
- chr2:88,857,161–89,268,506, 41 genes, copy number 9: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32, IGKV1-33.
- chr3:130,111,669–130,201,336, 2 genes, copy number 5 (within-gene range 1–5): LINC02021, ENPP7P3.

Autosomal genes at a single copy (total copy number 1): 10,729. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
